TCGA case TCGA-AA-3696 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa909ffb-03e1-4e3f-8888-2212b23d90b7

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 75 years; Vital status: Dead; Days to death: 153 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 75.7 years (27,667 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 153 days.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 26; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 153.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-AA-3696-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AA-3696-01A-01-TS1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-AA-3696-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AA-3696-10A, TCGA-AA-3696-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 153 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 153 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 153 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AA-3696-01): tumor purity 0.83, ploidy 2.27, whole-genome doublings 0 (call status: legacy_call).
